Gene-level copy-number profile of tumor specimen ALCH-B2XA-TTP1-A from ALCHEMIST case ALCH-B2XA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,719 days).
Specimen ALCH-B2XA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 58dbff99-22a0-4ff0-8175-4ef4812bea3c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2XA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/f2f32ff8-032b-4be5-9e66-ec5dc44d9c7d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 549; copy number 1: 283; copy number 2: 6,542; copy number 3: 16,110; copy number 4: 14,767; copy number 5: 8,411; copy number 6: 4,424; copy number 7: 4,255; copy number 8: 1,447; copy number 9: 786; copy number 10: 576; copy number 11: 224; copy number 12: 197; copy number 13: 140; copy number 14: 2; copy number 15: 75; copy number 16: 63; copy number 17: 54.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,234,174–89,600,680, 13 genes (within-gene range 0–3): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:18,560,047–18,560,191, 1 gene (within-gene range 0–2): CR383656.7.
- chr21:8,701,461–9,368,775, 16 genes: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.
- chr21:10,640,028–13,016,692, 3 genes: AF254982.1, IGHV1OR21-1, AP001464.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 7,819 genes in 65 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–180,566,523, 1,198 genes, copy number 7 (broad region; genes not listed).
- chr2:5,549,780–27,139,410, 356 genes, copy number 7–13 (broad region; genes not listed).
- chr2:41,143,780–51,225,575, 163 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr2:130,006,200–130,129,222, 9 genes, copy number 7–14: ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr2:172,423,807–195,737,702, 326 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr2:195,737,703–199,471,266, 46 genes, copy number 8–11 (within-gene range 5–11): DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1.
- chr2:231,037,523–231,926,396, 36 genes, copy number 7: C2orf72, AC009407.1, PSMD1, HTR2B, RNU1-93P, ARMC9, RPS28P4, MIR4777, AC017104.1, B3GNT7, ZBTB8OSP2, HIGD2AP1, AC017104.2, NCL, SNORA75, SNORD20, SNORD82, AC017104.4, RNU2-22P, LINC00471, NMUR1, RPL21P35, RPL23AP26, TEX44, RN7SL499P, PTMA, U4, MIR1244-1, PDE6D, AC073476.3, COPS7B, RPL28P2, AC073476.2, AC073476.1, MIR1471, NPPC.
- chr3:93,843,764–112,409,134, 234 genes, copy number 8 (broad region; genes not listed).
- chr4:51,843,000–54,295,272, 36 genes, copy number 7 (within-gene range 6–7): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2.
- chr5:58,198–1,634,005, 60 genes, copy number 8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:24,487,100–26,013,025, 22 genes, copy number 9: CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P.
- chr5:31,053,565–45,895,970, 242 genes, copy number 7–11 (broad region; genes not listed).
- chr6:60,719,222–134,707,349, 901 genes, copy number 7 (broad region; genes not listed).
- chr7:37,032–1,504,389, 41 genes, copy number 7: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1.
- chr7:6,952,625–29,013,367, 316 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:82,862,779–88,328,025, 74 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:89,243,401–91,398,155, 30 genes, copy number 11–12: RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:92,460,539–93,700,433, 11 genes, copy number 12–13 (within-gene range 6–13): AC091096.1, AC104211.1, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535.
- chr8:93,259,667–93,926,068, 16 genes, copy number 12 (within-gene range 6–12): AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2.
- chr8:104,330,324–134,979,279, 358 genes, copy number 8–10 (broad region; genes not listed).
- chr8:143,816,344–143,878,467, 7 genes, copy number 7: PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1.
- chr11:65,261,920–71,863,658, 294 genes, copy number 7–17 (broad region; genes not listed).
- chr11:72,940,498–73,761,137, 21 genes, copy number 8: AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1.
- chr11:74,988,279–88,045,608, 230 genes, copy number 7–12 (within-gene range 4–17) (broad region; genes not listed).
- chr12:12,310–24,949,101, 631 genes, copy number 8 (broad region; genes not listed).
- chr12:50,175,788–50,821,162, 17 genes, copy number 10: LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2.
- chr12:65,017,468–66,292,987, 33 genes, copy number 8: AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166.
- chr12:68,808,177–75,511,636, 100 genes, copy number 7 (broad region; genes not listed).
- chr12:76,721,534–78,213,010, 13 genes, copy number 7: RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1.
- chr12:80,707,634–85,882,992, 42 genes, copy number 7: MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS.
- chr12:88,033,846–104,350,307, 305 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr13:114,234,887–114,337,626, 7 genes, copy number 7: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:21,841,240–53,991,995, 683 genes, copy number 7–13 (broad region; genes not listed).
- chr14:77,201,026–79,974,169, 39 genes, copy number 8–11 (within-gene range 3–11): AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA, FXNP1, NRXN3, RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1, AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1, AF123462.1.
- chr15:34,489,002–37,967,724, 57 genes, copy number 7: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, GJD2, AC087457.1, ACTC1, TUBAP11, AQR, AC018868.1, ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2, AC021231.3, NANOGP8, AC021231.2, AC021231.1, PRELID1P4, ANP32AP1, DPH6, NUTF2P6, RBM17P4, MIR3942, AC019288.1, HNRNPA1P45, DPH6-DT, AC068867.1, LINC02853, MIR4510, AC021351.1, AC087516.1, AC087516.2, COX6CP4, CDIN1, AC103988.1, LARP4P, TPST2P1, AC013640.1, CSNK1A1P1, U3, AC018563.1, MEIS2, MIR8063, Y_RNA, AC078909.1, AC078909.2, Metazoa_SRP, AC087283.1, AC068875.1, AC016304.1, TMCO5A.
- chr15:100,372,936–101,979,093, 63 genes, copy number 7 (broad region; genes not listed).
- chr19:32,581,190–39,709,444, 356 genes, copy number 7–15 (broad region; genes not listed).
- chr19:41,449,520–45,730,896, 217 genes, copy number 7–16 (broad region; genes not listed).
- chr19:54,189,938–54,672,591, 50 genes, copy number 8: TSEN34, AC245052.1, RPS9, AC245052.2, LILRB3, AC245052.7, AC245052.3, LILRA6, AC245052.6, LILRB5, RNU6-1307P, AC245052.5, LILRB2, MIR4752, AC245884.5, AC245884.12, AC245884.7, AC245884.2, LILRA5, AC245884.11, VN1R104P, AC245884.6, LILRA4, LAIR1, AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8, LENG8-AS1, AC245884.3, LENG8, LENG9, CDC42EP5, LAIR2, AC245036.1, KIR3DX1, AC245036.2, LILRA2, AC245036.5, LILRA1, AC245036.4, LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1.
- chr20:62,307,955–64,327,972, 124 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
